Surgical pathology report (de-identified scan), TCGA case TCGA-PR-A5PF, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Roswell Park, specimen TCGA-PR-A5PF-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN(S): A. LEFT ADRENAL MASS

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Left adrenal tumor

GROSS DESCRIPTION:

A. LEFT ADRENAL MASS

Received fresh labeled with the patient's identification and designated "left adrenal mass" is a portion of intact, unoriented red tan soft tissue with attached lobulated adipose tissue weighing 218 g and measuring 11 x 9.8 x 7.5 cm. The surface inked black. The specimen is sectioned to show an encapsulated, heterogeneous, cystic, tan-brown friable mass, 8 x 4.5 x 4 cm, demonstrating red hemorrhagic fluid. A portion of grossly unremarkable appearing golden orange adrenal gland, 6.5 x 2.4 x 0.9 cm surrounds the mass. Gross photograph is taken. A portion of the specimen is submitted for tissue procurement, representatively submitted:

A1-A4: Representative sections mass and capsule

A5-A10: Representative sections mass and adrenal gland

DIAGNOSIS:

A. ADRENAL GLAND, LEFT, ADRENALECTOMY:

- PHEOCHROMOCYTOMA

TUMOR SIZE: 8.0 X 4.5 X 4.0 CM.

CAPSULAR INVASION: PRESENT.

LYMPHOVASCULAR INVASION: PRESENT.

MITOTIC FIGURES: 1 TO 2 PER 10 HIGH POWER FIELDS

NUCLEAR PLEOMORPHISM: MODERATE

PATTERN OF GROWTH: DIFFUSE

EXTENSION INTO ADJACENT ADIPOSE TISSUE: PRESENT

- TUMOR IS LOCATED <0.1 CM FROM THE INKED SURGICAL MARGIN.

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A5

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
CYTOKERATIN 7	Negative	
CYTOKERATIN 20	Negative	
MIB1-Ki67	Positive	Low
CHROMOGRANIN A	Positive	
SYNAPTOPHYSIN	Positive	

ICD-0-3

Pheochromocytoma,
malignant 8700/3

site: Adrenal Gland NOS
C74.9

9/21/13

[page 2 of 2]
INHIBIN-ALPHA	Negative	
A103,MELAN-A		Equivocal
RENAL CELL	Negative	
CD 10	Positive	

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of the [redacted] the use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology Laboratory at [redacted] They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

Source: NCI Genomic Data Commons file 5bc87aac-2c90-4db9-8297-c8cc0292e380 (TCGA-PR-A5PF.4909D06E-4AED-480B-ABDA-534B36E6BA44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).